Somatic mutation profile of tumor specimen TCGA-ZN-A9VO-01A (aliquot TCGA-ZN-A9VO-01A-11D-A39R-32) from TCGA case TCGA-ZN-A9VO, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 36.3 years (13,243 days).
Specimen TCGA-ZN-A9VO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec78e625-255c-447e-8cc3-de16d859d2bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZN-A9VO-10A (Blood Derived Normal), aliquot TCGA-ZN-A9VO-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0f015d7-9429-4281-a85b-1625eb15c9e8

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Splice Region 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN5 | c.1240G>A p.G414S (on ENST00000456580; = p.G374S on NM_004055.5) | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782148894, COSV53688860; called by muse, mutect2
- CDH19 | c.1160C>G p.S387* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV50954263; called by muse, mutect2, varscan2
- DAPL1 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV59375526; called by muse, mutect2, varscan2
- H2AC21 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV58612534; called by muse, mutect2
- NF2 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV58519871; called by muse, mutect2, varscan2
- NOC4L | c.1320C>T p.A440= | Splice Region (SNP) | VAF 29/106 reads (27%) | catalogued as rs771941255; called by muse, mutect2, varscan2
- PEX10 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375649043; ClinVar: uncertain significance; called by muse, mutect2
- ROCK1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67695149; called by muse, mutect2, varscan2
- ARFGEF1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- GRIN3B | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HAPLN1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NPFFR1 | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PLEKHG5 | c.2266G>A p.E756K (on ENST00000400915 / NM_001042663.3; = p.E719K on NM_020631.6) | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PTCH1 | c.*2G>C | Splice Region (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- SERPINB12 | c.763T>A p.F255I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ASAP1 | c.996A>T p.L332= | Silent (SNP) | VAF 17/194 reads (9%) | called by muse, mutect2
- COL20A1 | c.3372C>T p.I1124= | Silent (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- GPRIN2 | c.781C>T p.L261= | Silent (SNP) | VAF 76/460 reads (17%) | called by muse, mutect2, varscan2
- HECTD1 | c.4842T>C p.S1614= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- MAB21L3 | c.1077C>T p.I359= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs138505642; called by muse, mutect2, varscan2
- ZNF543 | c.870G>A p.K290= | Silent (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*2C>T | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
